Surgical pathology report (de-identified scan), TCGA case TCGA-ZP-A9D1, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Medical College of Wisconsin, specimen TCGA-ZP-A9D1-01A (Primary Tumor).

[page 1 of 3]
Results History

SURG PATH FINAL REPORT

Entry Information

Entry Date and Time

Lab Status
Final result

Entered by

Component Results

Component

SURG PATH FINAL REPORT

Accession #:

Specimen:

Date of Procedure:

Performing Clinician:

A. Liver segment 4

Clinical Notes:

Hepatocellular carcinoma. Cirrhosis. Specimen A: Fresh
tissue saved for tissue bank.

Diagnosis:

- A. Liver, segment 4, resection:
- Multifocal moderately differentiated hepatocellular carcinoma with background cirrhosis.
- AJCC Stage: pT1, NX, MX.
- Please see Tumor Characteristics.

IMMUNOHISTOCHEMISTRY DISCLAIMER: This test was developed and its performance characteristics determined by

It has not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. By placing the electronic signature on this report, the pathologist certifies that all positive and negative immunohistochemistry controls were reviewed and approved.

(Electronically signed by)
Verified:

Tumor Characteristics:

A: Liver, Resection (AJCC 7th Ed., 2010)

SPECIMEN TYPE:

Liver segment 4

TUMOR SIZE:

Greatest dimension: 2.8 cm

Additional dimensions: 2.7 x 2.1 cm

ICD-O-3

Carcinoma, hepatocellular NOS
8120/3

Site: Liver C22.0

JW 3/3/14

[page 2 of 3]
[REDACTED]

HISTOLOGIC TYPE:
Hepatocellular carcinoma
HISTOLOGIC GRADE:
GII: Moderately differentiated
PRIMARY TUMOR (pT):
pT1: Solitary tumor without vascular invasion
REGIONAL LYMPH NODES (pN):

Accession #:

pNX: Regional lymph nodes cannot be assessed
DISTANT METASTASIS (pM):
Specify site(s), if known: pMX: Metastasis cannot be assessed

MARGINS:

Parenchymal margin uninvolved by invasive carcinoma
Distance of invasive carcinoma from closest margin: 5 mm

LYMPH-VASCULAR INVASION:

Macroscopic Venous (Large Vessel) Invasion

Not identified

Microscopic (Small Vessel) Invasion

Not identified

ADDITIONAL PATHOLOGIC FINDINGS:

Cirrhosis/fibrosis

Gross:

A. The specimen is labeled "liver segment 4." Received in and placed in formalin is a 50 gram, 6.4 x 5.6 x 3.5 cm, piece of liver. One surface is covered by a light tan capsule. This surface has a raised nodular mass which is located beneath the capsule and does not disrupt the capsule. The roughened resection margins are inked black. The specimen is serially sectioned. The cut surface of the liver parenchyma is composed of small white-yellow nodules interspersed by white fibrous bands. The mass which was identified at the capsular surface measures 2.8 x 2.7 x 2.1 cm. The mass is well-circumscribed and has a lobular, light tan cut surface. This mass measures 0.5 cm from the nearest black inked margin. Tissue was taken for tissue bank. Representative sections are submitted as follows:

Cassette Designation:

A1-2	Mass with closest margin
A3-5	Representative sections of mass
A6-7	Representative sections of liver parenchyma

[page 3 of 3]
Microscopic:

A histological examination has been performed.

A. Sections show a liver parenchyma that exhibits areas of
_regenerative nodules with background cirrhotic liver that

Accession #:

surround multiple nodules of well differentiated hepatocellular carcinoma. The tumor cells are characterized by occasional pseudoglandular architecture and trabecular formations with prominent vasculature. The tumor cells are variably vacuolated and contain flocculent clear cytoplasm with mildly pleomorphic ovoid nuclei and prominent nucleoli. Occasional fibrous bands are admixed with the tumor cell infiltrate.

A special stain for trichrome highlights the background cirrhosis. A reticulin stain demonstrates hepatic cells with increased thickening of cell layers. An immunohistochemical stain for glypican-3 demonstrates cytoplasmic positivity in the tumor cell population. The controls are stained appropriately.

Administrative Notes:

CPT:

No charge codes are associated with this case.

Entry Information

Entry Date and Time	Lab Status	Entered by
	In process	

Criteria	hw 12/16/13	Yes	No
Prior Malignancy History	(R) Kidney	✓	

Source: NCI Genomic Data Commons file 6a8c4462-0ac1-4096-877a-b4ab8cd2a6f6 (TCGA-ZP-A9D1.2FA60C52-0164-432D-BB08-A8638AAF2C2F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).